Somatic mutation profile of tumor specimen TCGA-A2-A1FX-01A (aliquot TCGA-A2-A1FX-01A-11D-A13L-09) from TCGA case TCGA-A2-A1FX, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 61.2 years (22,344 days).
Specimen TCGA-A2-A1FX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8df04faa-c266-49de-a9ff-0eb29b0ef617.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A1FX-10A (Blood Derived Normal), aliquot TCGA-A2-A1FX-10A-01D-A13O-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d435c79a-d6c7-4ab6-bb34-1b77db8c04b4

The open-access MAF lists 27 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 20, Silent 5, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATXN3 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61497500; called by muse, mutect2, varscan2
- BRD8 | c.177C>A p.F59L | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99137651; called by muse, mutect2
- CAD | c.5863C>T p.R1955W | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs182811252, COSV53026761; called by muse, mutect2
- CREB5 | c.227G>T p.S76I (on ENST00000357727 / NM_182898.4; = p.S69I on NM_004904.3) | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV100745521; called by muse, mutect2
- CTNNA1 | c.1900-1G>T p.X634_splice | Splice Site (SNP) | VAF 15/63 reads (24%) | catalogued as COSV57080251; called by muse, mutect2, varscan2
- DNER | c.552G>T p.Q184H | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV100520054; called by muse, mutect2
- ERG | c.1267C>A p.P423T (on ENST00000398919 / NM_001243428.1; = p.P399T on NM_004449.4) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV55738169; called by muse, mutect2, varscan2
- FUT9 | c.359T>C p.L120S | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100134386; called by muse, mutect2
- H2AP | c.186C>A p.D62E | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.831); catalogued as COSV100586951; called by muse, mutect2
- ITPR3 | c.1059C>G p.C353W | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as COSV65414113; called by muse, mutect2, varscan2
- KRTAP10-7 | c.353T>A p.V118D | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.7); catalogued as COSV59112833; called by muse, mutect2, varscan2
- KRTAP19-2 | c.34T>A p.F12I | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.151); catalogued as COSV61855092; called by muse, mutect2, varscan2
- NRK | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as rs775671567, COSV54604984; called by muse, mutect2, varscan2
- PIK3C2B | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 19/29 reads (66%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV65804169; called by muse, mutect2, varscan2
- PLCH1 | c.1522G>T p.E508* (on ENST00000340059 / NM_001130960.2; = p.E520* on NM_014996.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 5/22 reads (23%) | catalogued as COSV58207026, COSV58208533; called by muse, mutect2, varscan2
- PLD5 | c.472C>A p.H158N (on ENST00000442594; = p.H96N on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT tolerated (0.92); PolyPhen benign (0.038); catalogued as COSV59164555; called by muse, mutect2, varscan2
- SMARCA1 | c.1455T>A p.S485R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV64413495; called by muse, mutect2, varscan2
- STXBP2 | c.1700C>G p.S567C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV55405291; called by muse, varscan2
- TRRAP | c.3251C>T p.S1084L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV62844259; called by muse, mutect2, varscan2
- ZBTB38 | c.3103G>A p.E1035K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1319742305, COSV58543897; called by muse, mutect2, varscan2
- ZNF629 | c.2473A>G p.S825G | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV52700446; called by muse, mutect2, varscan2
- NUP155 | c.532C>A p.L178I (on ENST00000231498 / NM_153485.3; = p.L119I on NM_004298.4) | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.101); called by muse, mutect2
- ACVR2B | c.438C>T p.I146= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as rs202022139, COSV61702596; called by muse, mutect2, varscan2
- ATXN1 | c.2301G>A p.A767= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV55228783; called by muse, mutect2, varscan2
- KCNN1 | c.1290C>T p.A430= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as COSV99716349; called by muse, mutect2
- SLC5A6 | c.267G>A p.P89= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs777285684, COSV100143585; called by muse, mutect2
- UNC13D | c.705G>A p.K235= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV52886925; called by muse, mutect2, varscan2
